Surgical pathology report (de-identified scan), TCGA case TCGA-VR-AA7D, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-AA7D-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD O 3

Carcinoma, squamous
cell NOS 8670/3

Site Esophagus, middle
third C15.4

4/3/19/14

PATHOLOGY REPORT:

PRIMARY SITE: Esophagus (Mid third)

- 1- Material designated as "cervical lymph node":
- Congested parathyroid showing volumetric increase.

Note: depending on the correlation with clinical/radiological findings, the present case may correspond to hyperplasia or parathyroid adenoma.

2 - "Esophagectomy and partial gastrectomy":

- Moderately differentiated squamous cell carcinoma, measuring 7.5 cm, infiltrating the wall of the esophagus up to periesophageal adipose tissue;
- Angiolymphatic invasion present;
- Perineural invasion present;
- Scarce peritumoral desmoplasia;
- Moderate lymphocytic peritumoral infiltrate;
- Surgical margins free of neoplasia;
- Fragments of non-neoplastic esophageal mucosa showing congestion;
- Fragments of gastric mucosa with moderate chronic gastritis with atrophy and intestinal metaplasia;
- Metastasis to 7 of 13 dissected lymph nodes (11/13).

3 - "Margin of esophagus":

- Free of neoplasia.

Source: NCI Genomic Data Commons file d5976b5a-7ecf-462f-a65f-bbee999b13cb (TCGA-VR-AA7D.EE9D31A7-6B04-4C6F-94CD-10A1907D5B1D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).